Gene-level copy-number profile of tumor specimen TCGA-DM-A1D7-01A from TCGA case TCGA-DM-A1D7, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 82.5 years (30,142 days).
Specimen TCGA-DM-A1D7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.58376c73-ecd9-4b2b-bc62-6959396cc2b6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DM-A1D7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2af60eb9-c4dc-4e94-83d1-115657046e99

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,548; copy number 3: 7,505; copy number 4: 40,633; copy number 5: 5,576; copy number 6: 518; copy number 7: 37; copy number 8: 311; copy number 10: 196; copy number 11: 324; copy number 12: 89; copy number 13: 16; copy number 16: 55; copy number 17: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DM-A1D7-01A-11D-A151-01): tumor purity 0.72, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 677 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:40,271,566–44,380,179, 153 genes, copy number 12–17 (within-gene range 6–17) (broad region; genes not listed).
- chr12:1,970,786–2,697,950, 1 gene, copy number 11 (within-gene range 2–11): CACNA1C.
- chr12:2,217,462–8,438,425, 245 genes, copy number 11 (broad region; genes not listed).
- chr12:15,322,257–17,711,046, 30 genes, copy number 10–13 (within-gene range 2–13): PTPRO, AC092183.1, EPS8, RNU6-251P, AC073651.1, AC073651.2, STRAP, DERA, EGLN3P1, SLC15A5, MGST1, SUPT16HP1, AC007528.1, AC007552.1, LMO3, AC007552.2, AC007529.2, AC007529.1, SKP1P2, EEF1A1P16, AC092793.1, RNU6-837P, AC092110.1, RPL7P40, PSMC1P8, TIMM17BP1, AC048352.1, LINC02378, MIR3974, Y_RNA.
- chr13:109,400,696–110,136,906, 14 genes, copy number 10–11: LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, AL390755.3.
- chr20:41,991,140–47,356,889, 164 genes, copy number 10–11 (broad region; genes not listed).
- chr20:57,957,126–61,940,617, 70 genes, copy number 10 (within-gene range 4–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
